Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANJ, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AANJ-01A (Primary Tumor).

[page 1 of 2]
Ord #=

SURGICAL PATHOL

RESULTED

Collect D/T=

Modifiers:

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Left testicle

Clinical History
Left testicular mass

Gross Description

Received in formalin and consists of Left testicle measuring 9 x 5 x 4.5 cm. that is firm and enlarged with an attached spermatic cord measuring 7 cm. in length and 1.5 cm. in diameter. Upon bivalving the testicle it is entirely replaced by a fleshy, solid, tan-pink, multinodular mass. The surgical margin of the spermatic cord is inked blue and the rest of the spermatic cord is inked black. Representative sections are submitted.

- 1 spermatic cord margin
- 2 spermatic cord
- 3 epididymis
- 4-8 testicular mass

ICD-0-3
Seminoma NOS 9061/3
Site: @ Testis NOS C62.9
JAS 8/31/14

Date of dictation:

Gross Description By:

Microscopic Description
Performed.

Final Pathologic Diagnosis

Left testicle: Seminoma, 9 cm, limited to testes, extending into rete testis (slide 3). Tumor does not involve tunica vaginalis or epididymis. Lymphovascular invasion identified in spermatic cord, including cord margin.

[page 2 of 2]
(Continued)

Acct#:

Pathologic Stage: T2NXMXSX (Stage IB)

Attending Pathologist:

***Electronically Signed Out By

Patient Name:

Case #:

Med. Rec. #:

Location:

Date Collected:

Source: NCI Genomic Data Commons file 0e32bad2-a9df-48b7-8139-916c83c0a30a (TCGA-XE-AANJ.74AF0A3D-C4F4-4523-8CFC-46098FDC1860.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).